Somatic mutation profile of tumor specimen TCGA-AN-A0XW-01A (aliquot TCGA-AN-A0XW-01A-11D-A10G-09) from TCGA case TCGA-AN-A0XW, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 36.2 years (13,208 days).
Specimen TCGA-AN-A0XW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28b4bf1c-5f5f-464a-a2f3-1d887644b51b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A0XW-10A (Blood Derived Normal), aliquot TCGA-AN-A0XW-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bd8c00d-0e12-4ee7-9839-5edd11e9fa59

The open-access MAF lists 328 somatic variants for this specimen: 247 protein-altering or splice-affecting, 73 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 217, Silent 73, Nonsense Mutation 23, Frame Shift Ins 3, RNA 3, Splice Region 2, Intron 2, 5'UTR 2, Splice Site 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.384G>C p.K128N | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1114167645, CM135244, COSV64289333, COSV64307391; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABAT | c.1080G>A p.M360I | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV51629024; called by muse, mutect2, varscan2
- ABCA1 | c.6082G>T p.A2028S | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV101036999; called by muse, mutect2
- ABCA8 | c.3777G>C p.K1259N | Missense Mutation (SNP) | VAF 7/170 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV99285843; called by muse, mutect2
- ACBD4 | c.276G>A p.M92I | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.18); PolyPhen benign (0.131); catalogued as COSV100416183; called by muse, varscan2
- ACER3 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 77/2895 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV99568342; called by muse, mutect2
- ACKR3 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.6); catalogued as COSV56021647; called by muse, mutect2, varscan2
- ADGRG2 | c.1285G>A p.D429N (on ENST00000379869 / NM_001079858.3; = p.D426N on NM_005756.4) | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV61341681; called by muse, mutect2, varscan2
- AFF3 | c.2353G>C p.E785Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV57876409; called by muse, mutect2, varscan2
- ANOS1 | c.276A>C p.E92D | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV52927366; called by muse, mutect2, varscan2
- APOB | c.7999G>C p.E2667Q | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs983763232, COSV51955566; called by muse, mutect2, varscan2
- APOL2 | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV50772291, COSV50773384; called by muse, mutect2, varscan2
- ARHGAP26 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as COSV99190972; called by muse, mutect2, varscan2
- ARHGDIB | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 6/137 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99967358; called by muse, mutect2
- ARNT | c.2281G>C p.E761Q | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.26); catalogued as COSV99648759; called by muse, mutect2
- ARSF | c.1258C>T p.Q420* | Nonsense Mutation (SNP) | VAF 4/70 reads (6%) | catalogued as COSV100839512, COSV100839627; called by muse, mutect2
- ASCC3 | c.5005G>C p.D1669H | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64981804; called by muse, mutect2, varscan2
- ASXL3 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99325021; called by muse, mutect2
- ATP6V0A1 | c.2390C>T p.S797L (on ENST00000343619 / NM_001378531.1; = p.S791L on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1429933097, COSV99230467; called by muse, mutect2
- BIRC6 | c.14309G>A p.C4770Y | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101428156, COSV70207001; called by muse, mutect2, varscan2
- BOD1L1 | c.7351G>A p.E2451K | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs752909060, COSV50081253; called by muse, mutect2, varscan2
- BTRC | c.226C>G p.L76V (on ENST00000370187 / NM_033637.4; = p.L40V on NM_003939.5) | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.745); catalogued as COSV100926562; called by muse, mutect2
- C2orf16 | c.3975G>C p.K1325N | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as COSV62678747; called by muse, mutect2, varscan2
- C4BPA | c.1507G>C p.E503Q | Missense Mutation (SNP) | VAF 45/628 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.596); catalogued as COSV100891106, COSV65535695; called by muse, mutect2
- C4orf3 | c.53G>C p.R18P | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV67581702, COSV67582049; called by muse, mutect2, varscan2
- C5 | c.1643G>A p.G548E | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99797928; called by muse, mutect2
- C7 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.77); catalogued as COSV57482167; called by muse, mutect2, varscan2
- CABS1 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV99909077; called by muse, mutect2, varscan2
- CACNA1G | c.971C>G p.S324* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV100662306, COSV61741247; called by muse, mutect2
- CACNA1G | c.1116C>A p.F372L | Missense Mutation (SNP) | VAF 20/612 reads (3%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.613); catalogued as rs867835820, COSV100661867, COSV61721471, COSV61732414; called by muse, mutect2
- CACNA2D2 | c.1479G>C p.L493= | Splice Region (SNP) | VAF 7/21 reads (33%) | catalogued as COSV56569920; called by muse, mutect2, varscan2
- CADPS | c.3748G>A p.E1250K | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV51882892, COSV99338467; called by muse, mutect2, varscan2
- CALCOCO2 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 45/492 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.454); catalogued as COSV99363786; called by muse, mutect2
- CCDC180 | c.279G>C p.K93N | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as COSV63836108; called by mutect2, varscan2
- CDC25A | c.363G>C p.R121S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV56772540; called by muse, mutect2, varscan2
- CEP250 | c.3067G>A p.D1023N | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV61175136; called by muse, mutect2, varscan2
- CHD9 | c.944G>C p.R315T | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV101272137; called by muse, mutect2
- CHD9 | c.1162G>C p.E388Q | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.094); catalogued as COSV101272138; called by muse, mutect2
- CLC | c.187G>C p.V63L | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV55684834, COSV55686619; called by muse, mutect2, varscan2
- CLTC | c.3040G>C p.D1014H | Missense Mutation (SNP) | VAF 25/730 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as COSV99292316, COSV99292854; called by muse, mutect2
- CLUAP1 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.336); catalogued as COSV58895305; called by muse, mutect2, varscan2
- CMTR1 | c.2374C>T p.H792Y | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1484888185, COSV64982913; called by muse, mutect2, varscan2
- CMYA5 | c.7810G>A p.E2604K | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as rs1283398515, COSV71410096; called by muse, mutect2, varscan2
- CNKSR1 | c.1025C>T p.S342F (on ENST00000374253 / NM_001297647.2; = p.S335F on NM_006314.3) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV64164360; called by muse, mutect2, varscan2
- CNTN2 | c.1001C>G p.S334W | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV59353511; called by muse, mutect2, varscan2
- COL14A1 | c.2462C>T p.S821F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52870669; called by muse, mutect2, varscan2
- CR1 | c.5996G>T p.R1999I | Missense Mutation (SNP) | VAF 50/1240 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100887622; called by muse, mutect2
- CRTAP | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs766089362, COSV58015233; called by muse, mutect2, varscan2
- CTNNA1 | c.1294G>C p.E432Q | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.405); catalogued as COSV57082184; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1807C>T p.H603Y | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.099); catalogued as COSV54747468; called by muse, mutect2, varscan2
- CYLC1 | c.252T>G p.I84M | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.465); catalogued as COSV100254672; called by muse, mutect2
- CYP1B1 | c.1444C>G p.L482V | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); catalogued as COSV52230255; called by muse, mutect2, varscan2
- CYP2A13 | c.1337G>A p.R446K | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.164); catalogued as COSV57838301; called by muse, mutect2, varscan2
- DDX43 | c.87G>T p.R29S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); catalogued as COSV100946443, COSV64838070; called by muse, mutect2, varscan2
- DENND6A | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV60768718; called by muse, mutect2, varscan2
- DEUP1 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.17); catalogued as COSV99977171; called by muse, mutect2
- DGKE | c.1165C>T p.H389Y | Missense Mutation (SNP) | VAF 35/819 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.786); catalogued as COSV99400925, COSV99400954; called by muse, mutect2
- DMBT1 | c.5467C>T p.R1823W (on ENST00000338354 / NM_001377530.1; = p.R1066W on NM_004406.3) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.959); catalogued as rs545733226, COSV57536112; called by muse, mutect2, varscan2
- DMXL1 | c.2576C>G p.S859* | Nonsense Mutation (SNP) | VAF 58/178 reads (33%) | catalogued as COSV60722235; called by muse, mutect2, varscan2
- DMXL1 | c.8379G>C p.M2793I | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV60722254; called by muse, mutect2, varscan2
- DMXL2 | c.6619C>G p.L2207V | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99196401; called by muse, mutect2
- DNAH9 | c.1243C>G p.L415V | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.26); catalogued as COSV52379749; called by muse, mutect2, varscan2
- DRG1 | c.732C>G p.I244M | Missense Mutation (SNP) | VAF 56/303 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV58919029; called by muse, mutect2, varscan2
- EFEMP1 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.42); catalogued as COSV100816850; called by muse, mutect2
- EIF3E | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 55/318 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV55206427; called by muse, mutect2, varscan2
- ERC2 | c.1426G>C p.E476Q | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55668803, COSV55669829; called by muse, mutect2, varscan2
- ERLEC1 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as rs1165323990, COSV99483046; called by muse, mutect2
- ETF1 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.269); catalogued as COSV62127308; called by muse, mutect2, varscan2
- ETV3 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as COSV58748633; called by muse, mutect2, varscan2
- EVPL | c.5035G>C p.E1679Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56916763; called by mutect2, varscan2
- EXO1 | c.1522dup p.C508Lfs*7 | Frame Shift Ins (INS) | VAF 40/211 reads (19%) | catalogued as rs763386152; called by mutect2, varscan2
- EZH2 | c.1916C>G p.S639* (on ENST00000460911 / NM_001203247.2; = p.S644* on NM_004456.5) | Nonsense Mutation (SNP) | VAF 34/144 reads (24%) | catalogued as COSV100235997, COSV57451775; called by muse, mutect2, varscan2
- FAM155A | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs1229236647, COSV65590077; called by muse, mutect2, varscan2
- FAM214A | c.1748G>C p.R583T | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV55927618; called by muse, mutect2, varscan2
- FAM47C | c.115A>G p.R39G | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV100792589; called by muse, mutect2
- FARP1 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV100130756; called by muse, mutect2
- FBXO3 | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 77/281 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.339); catalogued as rs757358495, COSV55768291; called by muse, mutect2, varscan2
- FER1L6 | c.2258G>A p.C753Y | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101205885; called by muse, mutect2
- FGD4 | c.442G>C p.D148H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99847087; called by muse, mutect2
- FIP1L1 | c.1586G>C p.R529T | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV99820020; called by muse, mutect2
- FKTN | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56312548; called by muse, mutect2, varscan2
- FLNC | c.5838C>G p.I1946M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV57966306; called by muse, mutect2, varscan2
- FOSL2 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1436464399, COSV99268355; called by muse, mutect2
- FRY | c.1201C>T p.R401* | Nonsense Mutation (SNP) | VAF 44/123 reads (36%) | catalogued as rs1399764760, COSV66567390; called by muse, mutect2, varscan2
- GABRB3 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV54686326; called by muse, mutect2, varscan2
- GATAD1 | c.505C>G p.Q169E | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55319881, COSV99843693; called by muse, mutect2
- GCC2 | c.2272C>A p.Q758K | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV59180483; called by muse, mutect2, varscan2
- GLMP | c.1191G>T p.K397N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.429); catalogued as rs1273712691, COSV99827922; called by muse, mutect2
- GLYCTK | c.1554G>C p.L518F | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as COSV59794872; called by muse, mutect2, varscan2
- GMFB | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 27/191 reads (14%) | catalogued as COSV63738215; called by muse, varscan2
- GNPTAB | c.3226G>A p.E1076K | Missense Mutation (SNP) | VAF 63/230 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV73418414; called by muse, mutect2, varscan2
- GPX6 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100724840; called by muse, mutect2
- GSPT2 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 10/281 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100468187, COSV99080183; called by muse, mutect2
- GYS2 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as COSV99679792; called by muse, mutect2
- H2AC4 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52520172; called by muse, mutect2, varscan2
- HDLBP | c.1873G>C p.E625Q | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV100190938, COSV60501651; called by muse, mutect2, varscan2
- HLA-G | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as rs1417469901, COSV100827090; called by muse, mutect2
- HMCN1 | c.14075G>A p.C4692Y | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54946306; called by muse, mutect2, varscan2
- HOXA2 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as rs758080122, COSV56067964; called by muse, mutect2, varscan2
- HSPA4 | c.254C>G p.S85C | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as COSV59183743; called by muse, mutect2, varscan2
- HTR2A | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV66328110, COSV66328592; called by muse, mutect2, varscan2
- HUWE1 | c.7390G>A p.E2464K | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV53343936; called by muse, mutect2
- HUWE1 | c.529T>A p.F177I | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV53366279; called by muse, mutect2, varscan2
- HYDIN | c.7131G>A p.M2377I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV59258583; called by mutect2, varscan2
- IARS1 | c.1143G>C p.L381F | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65117390; called by muse, mutect2, varscan2
- IGF1R | c.3003G>A p.M1001I | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1163550820, COSV99151438; called by muse, mutect2, varscan2
- IL23R | c.554C>G p.S185* | Nonsense Mutation (SNP) | VAF 13/86 reads (15%) | catalogued as COSV61376581; called by muse, mutect2, varscan2
- IL6ST | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as rs750312883, COSV61143098; called by muse, mutect2
- INSR | c.1889C>T p.S630L | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV57174358; called by muse, mutect2, varscan2
- INTS4 | c.1369G>C p.E457Q | Missense Mutation (SNP) | VAF 29/639 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV101417196; called by muse, mutect2
- ITPKC | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV99648763; called by muse, mutect2, varscan2
- KIF13A | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52467559; called by muse, mutect2, varscan2
- KIF4A | c.2329G>C p.D777H | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.752); catalogued as COSV63285200, COSV63285206; called by muse, mutect2, varscan2
- KIF5B | c.1264G>T p.E422* | Nonsense Mutation (SNP) | VAF 80/356 reads (22%) | catalogued as COSV56656684; called by muse, mutect2, varscan2
- KMT2C | c.11533G>C p.E3845Q | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100072141, COSV51457984; called by muse, mutect2
- KRT6A | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs369911781; called by muse, mutect2, varscan2
- KRT84 | c.380G>C p.G127A | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57774026; called by muse, mutect2, varscan2
- KTN1 | c.2381C>T p.S794F | Missense Mutation (SNP) | VAF 45/317 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV63215852; called by muse, mutect2, varscan2
- LAMC1 | c.2769C>G p.F923L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV51184884; called by muse, mutect2, varscan2
- LARP6 | c.712G>C p.E238Q | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV100150866; called by muse, mutect2
- LMAN2 | c.106C>G p.L36V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.063); catalogued as COSV57426048; called by mutect2, varscan2
- LPO | c.145T>G p.F49V | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV51863139; called by muse, mutect2, varscan2
- LRRFIP1 | c.731G>C p.R244T (on ENST00000392000 / NM_001137552.2; = p.R220T on NM_004735.4) | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV55257755; called by muse, mutect2, varscan2
- LTBP1 | c.2878G>C p.E960Q (on ENST00000404816 / NM_206943.4; = p.E634Q on NM_000627.4) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV100617209, COSV63195429; called by muse, mutect2
- MDN1 | c.5086G>A p.E1696K | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.286); catalogued as COSV101021370; called by muse, mutect2
- MED13 | c.6513G>C p.M2171I | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as COSV67262389; called by muse, mutect2
- MED13 | c.5032C>T p.P1678S | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67267542; called by muse, mutect2, varscan2
- MEST | c.604C>G p.P202A | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as COSV56230062; called by muse, mutect2, varscan2
- MFAP1 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 32/299 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.406); catalogued as COSV51041809; called by muse, mutect2
- MRPL30 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as COSV57667771; called by muse, mutect2, varscan2
- MRPS35 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.271); catalogued as COSV50012704; called by muse, mutect2, varscan2
- MTMR6 | c.1267C>T p.L423F | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as rs778111295, COSV67809305, COSV67810003; called by muse, mutect2, varscan2
- MTMR7 | c.249C>G p.I83M | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV99472447; called by muse, mutect2
- MUC17 | c.4073C>G p.S1358* | Nonsense Mutation (SNP) | VAF 24/148 reads (16%) | catalogued as COSV60306016; called by muse, mutect2, varscan2
- MYH15 | c.5260G>A p.E1754K | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV56321265; called by muse, mutect2, varscan2
- MYO16 | c.3634G>A p.D1212N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV62763452; called by muse, mutect2, varscan2
- MYOM2 | c.116C>A p.S39Y | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV50788728; called by muse, mutect2, varscan2
- MYRIP | c.2361G>T p.R787S | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as COSV56883719; called by muse, mutect2, varscan2
- NAT9 | c.599G>A p.R200K | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV52855243; called by muse, mutect2, varscan2
- NAV1 | c.3314C>G p.S1105C | Missense Mutation (SNP) | VAF 123/280 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55217269, COSV55227555; called by muse, mutect2, varscan2
- NCKIPSD | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.755); catalogued as COSV53660182; called by muse, mutect2
- NF1 | c.7053C>G p.F2351L (on ENST00000358273 / NM_001042492.3; = p.F2330L on NM_000267.3) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV62223820; called by muse, mutect2, varscan2
- NPC1 | c.1756G>C p.E586Q | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV52584228; called by muse, mutect2, varscan2
- NRDE2 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV62964978; called by muse, mutect2, varscan2
- NTRK2 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs200996090, COSV52871889, COSV52885063; called by muse, mutect2, varscan2
- NUP160 | c.2420C>G p.S807C | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV101021341, COSV65856335; called by muse, mutect2, varscan2
- NUP210L | c.1876C>G p.L626V | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV55146489, COSV55147569; called by muse, mutect2, varscan2
- NXPE4 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.616); catalogued as COSV64943431, COSV99081006; called by muse, mutect2
- OR4D10 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.279); catalogued as COSV73260225; called by muse, mutect2, varscan2
- OTOGL | c.670C>G p.L224V (on ENST00000547103; = p.L215V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as COSV72006981, COSV72007630; called by muse, mutect2, varscan2
- PARP6 | c.1218G>C p.Q406H | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV53005402; called by muse, mutect2, varscan2
- PAXIP1 | c.2087C>T p.P696L | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68187773; called by muse, mutect2
- PCDHGA11 | c.703G>C p.D235H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53920028, COSV54046361; called by mutect2, varscan2
- PCOLCE2 | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 33/136 reads (24%) | catalogued as rs116059545; called by muse, mutect2, varscan2
- PCTP | c.220G>C p.D74H | Missense Mutation (SNP) | VAF 16/422 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99273798; called by muse, mutect2
- PCYOX1L | c.435G>T p.Q145H | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.395); catalogued as COSV51005891; called by muse, mutect2, varscan2
- PES1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as COSV58830010; called by muse, mutect2, varscan2
- PEX5L | c.315G>T p.L105F | Missense Mutation (SNP) | VAF 61/231 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55859032; called by muse, mutect2, varscan2
- PIK3C2G | c.1510G>C p.D504H | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56836927, COSV56841611; called by muse, mutect2, varscan2
- PKN3 | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV52580123; called by muse, mutect2, varscan2
- PKN3 | c.1944G>A p.M648I | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV52580136; called by muse, mutect2, varscan2
- PLEKHA4 | c.1678C>T p.P560S | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs763707559, COSV54366753; called by muse, mutect2, varscan2
- PLG | c.1993G>C p.D665H | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57516306, COSV57521797; called by muse, mutect2
- PML | c.1257C>T p.P419= | Splice Region (SNP) | VAF 5/18 reads (28%) | catalogued as rs543631733, COSV51454562; called by muse, mutect2, varscan2
- PNKP | c.1487C>G p.S496C | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV99681776; called by muse, mutect2
- POLB | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.028); catalogued as COSV99612474, COSV99612959; called by muse, mutect2
- PRMT2 | c.857C>G p.S286* | Nonsense Mutation (SNP) | VAF 42/176 reads (24%) | catalogued as rs754046386, COSV52456401, COSV52458202; called by muse, mutect2, varscan2
- PRR27 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV60641576; called by muse, mutect2, varscan2
- PSG8 | c.398G>C p.G133A | Missense Mutation (SNP) | VAF 17/287 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.37); catalogued as COSV100126220; called by muse, mutect2
- PTPN2 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.153); catalogued as COSV100518525, COSV58999606; called by muse, mutect2, varscan2
- RAD50 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.05); catalogued as COSV54758183; called by muse, mutect2, varscan2
- RAD54B | c.307C>G p.H103D | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV60251717, COSV60255405; called by muse, mutect2, varscan2
- RASA3 | c.1251G>C p.L417F | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766772336, COSV61871726, COSV61874423; called by muse, mutect2, varscan2
- RC3H2 | c.3007C>T p.Q1003* | Nonsense Mutation (SNP) | VAF 45/133 reads (34%) | catalogued as COSV61802799; called by muse, mutect2, varscan2
- RCVRN | c.490G>C p.D164H | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV99874202; called by muse, mutect2
- RDH11 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 9/82 reads (11%) | catalogued as COSV67283414; called by muse, mutect2, varscan2
- RMI1 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.03); catalogued as COSV100366268, COSV57937959; called by muse, mutect2
- ROBO1 | c.2295C>G p.I765M | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs756411742, COSV71399076; called by muse, mutect2, varscan2
- RSAD1 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as COSV51957679; called by muse, mutect2, varscan2
- RSF1 | c.2074G>C p.E692Q | Missense Mutation (SNP) | VAF 58/1675 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.203); catalogued as COSV100407245, COSV57840910; called by muse, mutect2
- RYR2 | c.3154G>A p.E1052K | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs1271333166, COSV63686700; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCFD2 | c.1390G>T p.E464* | Nonsense Mutation (SNP) | VAF 10/128 reads (8%) | catalogued as COSV101189379; called by muse, mutect2
- SCN2A | c.3067G>A p.E1023K | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs1397215259, COSV99331822; called by muse, mutect2
- SEC24C | c.1521G>C p.M507I | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as COSV100226833; called by muse, mutect2
- SEMA6D | c.1709-1G>C p.X570_splice | Splice Site (SNP) | VAF 57/275 reads (21%) | catalogued as COSV60385007; called by muse, mutect2, varscan2
- SERPINA11 | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as COSV58242029, COSV58243030; called by muse, mutect2, varscan2
- SETDB1 | c.2613G>C p.E871D | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54993392; called by muse, mutect2
- SFSWAP | c.1903G>C p.E635Q | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55521840, COSV99906117; called by muse, mutect2
- SGO2 | c.2024G>C p.R675T | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.022); catalogued as rs1217401617, COSV63415303, COSV63418546; called by muse, mutect2, varscan2
- SHC1 | c.556C>G p.Q186E (on ENST00000368445 / NM_183001.5; = p.Q76E on NM_003029.5) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100821073; called by muse, mutect2
- SHCBP1L | c.1737G>A p.M579I | Missense Mutation (SNP) | VAF 31/314 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100841002; called by muse, mutect2, varscan2
- SIK3 | c.2248C>T p.Q750* (on ENST00000445177 / NM_001366686.2; = p.Q708* on NM_025164.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | catalogued as COSV52624037; called by muse, mutect2, varscan2
- SIPA1L2 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53401355; called by muse, mutect2, varscan2
- SKP1 | c.228G>C p.E76D | Missense Mutation (SNP) | VAF 7/215 reads (3%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV100104513; called by muse, mutect2
- SLC4A11 | c.1471G>C p.E491Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66264297; called by muse, mutect2
- SNX2 | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV65349336; called by muse, mutect2, varscan2
- SOAT1 | c.868C>G p.P290A | Missense Mutation (SNP) | VAF 17/409 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as COSV100858965; called by muse, mutect2
- SOAT2 | c.581C>T p.T194M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV56858546; called by muse, mutect2
- SPART | c.1350G>C p.Q450H | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV100768744; called by muse, mutect2
- SSH2 | c.3709G>C p.E1237Q | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV52166337, COSV99282148; called by muse, mutect2
- SSH3 | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.845); catalogued as rs766959116, COSV100354582; called by muse, mutect2
- STK17A | c.799G>C p.D267H | Missense Mutation (SNP) | VAF 51/233 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV60048955; called by muse, mutect2, varscan2
- STK17B | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.835); catalogued as COSV55830308; called by muse, mutect2, varscan2
- SUSD5 | c.1409C>T p.S470L | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100535136; called by muse, mutect2
- SVEP1 | c.2975C>T p.S992L | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749900925, COSV57040929, COSV57049499; called by muse, mutect2, varscan2
- SVOP | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100139413; called by muse, mutect2
- SYCP1 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV65701349; called by muse, mutect2, varscan2
- SYMPK | c.2877G>A p.M959I | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99841646, COSV99841749; called by muse, mutect2, varscan2
- SYNE1 | c.11713G>A p.D3905N (on ENST00000367255 / NM_182961.4; = p.D3890N on NM_033071.3) | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.816); catalogued as COSV55120010; called by muse, mutect2, varscan2
- TANK | c.1033C>G p.L345V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV52048279; called by muse, varscan2
- TCF20 | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59496629; called by muse, mutect2
- TDRD6 | c.2718C>A p.F906L | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100287665; called by muse, mutect2
- TEX47 | c.616G>C p.D206H | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV51880443; called by muse, mutect2, varscan2
- TF | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as COSV53923969; called by muse, mutect2, varscan2
- TFPT | c.755C>G p.S252C | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.173); catalogued as COSV52928556; called by muse, mutect2
- THEM5 | c.636G>C p.Q212H | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV64313284; called by muse, mutect2, varscan2
- TLR8 | c.1816G>A p.E606K (on ENST00000218032 / NM_138636.5; = p.E624K on NM_016610.4) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV54321267, COSV54321280; called by muse, mutect2, varscan2
- TMEM132D | c.1960A>T p.K654* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as COSV67162851; called by muse, mutect2, varscan2
- TNFSF4 | c.158C>G p.S53* | Nonsense Mutation (SNP) | VAF 26/208 reads (13%) | catalogued as COSV56057846; called by muse, mutect2, varscan2
- TOP3A | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV58181458; called by muse, mutect2, varscan2
- TRAF6 | c.934C>G p.Q312E | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.186); catalogued as COSV100777700; called by muse, mutect2, varscan2
- TRAF6 | c.679-1G>C p.X227_splice | Splice Site (SNP) | VAF 8/156 reads (5%) | catalogued as COSV100777702; called by muse, mutect2
- TRAPPC1 | c.140C>G p.S47W | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58051565; called by muse, mutect2, varscan2
- TRIM37 | c.2192G>A p.R731K | Missense Mutation (SNP) | VAF 11/185 reads (6%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV99232962; called by muse, mutect2
- TSC1 | c.2230G>C p.E744Q | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV100051839; called by muse, mutect2
- TTN | c.22829G>A p.R7610K (on ENST00000591111; = p.R6683K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/167 reads (18%) | PolyPhen benign (0); catalogued as COSV100597486, COSV60387505; called by muse, mutect2, varscan2
- TTYH2 | c.1485G>C p.E495D | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53913897; called by muse, mutect2, varscan2
- UACA | c.3154G>C p.E1052Q | Missense Mutation (SNP) | VAF 78/260 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59860635; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3355G>A p.D1119N | Missense Mutation (SNP) | VAF 56/245 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54443321; called by muse, mutect2, varscan2
- UNC119B | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100763482; called by muse, mutect2, varscan2
- WDR3 | c.1045C>G p.L349V | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV62525580; called by muse, mutect2, varscan2
- ZCCHC9 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV54177527; called by muse, mutect2, varscan2
- ZFP37 | c.680G>C p.G227A | Missense Mutation (SNP) | VAF 25/393 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV100953271; called by muse, mutect2
- ZNF131 | c.909G>C p.W303C (on ENST00000509156 / NM_001330707.2; = p.W269C on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV61004736; called by muse, mutect2, varscan2
- ZNF197 | c.3075G>C p.E1025D | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.022); catalogued as COSV56077605; called by muse, mutect2, varscan2
- ZNF273 | c.481A>T p.R161* | Nonsense Mutation (SNP) | VAF 8/198 reads (4%) | catalogued as COSV100139331; called by muse, mutect2
- ZNF302 | c.837C>G p.I279M (on ENST00000627982; = p.I200M on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.847); catalogued as COSV101416497, COSV101416504, COSV101416522; called by muse, mutect2
- ZNF304 | c.914G>C p.R305T | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV56583197, COSV56586739; called by muse, mutect2, varscan2
- ZNF462 | c.1317C>G p.F439L | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.203); catalogued as COSV52952423; called by muse, mutect2, varscan2
- ZNF608 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV100102324, COSV60441885; called by muse, mutect2, varscan2
- ZNF677 | c.1014G>C p.Q338H | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.892); catalogued as COSV61721209, COSV61721809; called by muse, mutect2, varscan2
- ZNF692 | c.262C>T p.H88Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV60660416; called by muse, mutect2, varscan2
- ZNF700 | c.416C>G p.S139* | Nonsense Mutation (SNP) | VAF 33/270 reads (12%) | catalogued as COSV54315698; called by muse, mutect2, varscan2
- ATIC | c.708dup p.F237Ifs*45 | Frame Shift Ins (INS) | VAF 14/112 reads (13%) | called by mutect2, pindel, varscan2
- PIBF1 | c.1675dup p.S559Ffs*7 | Frame Shift Ins (INS) | VAF 53/188 reads (28%) | called by mutect2, pindel, varscan2
- TRDC | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TUBGCP5 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ABCB4 | c.2727G>A p.L909= | Silent (SNP) | VAF 35/241 reads (15%) | catalogued as COSV55942621; called by muse, mutect2, varscan2
- BACH1 | c.1320C>T p.I440= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV99728281; called by muse, mutect2
- BAIAP2L1 | c.1269C>T p.T423= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs555687728, COSV50061692; called by muse, mutect2, varscan2
- BUB1 | c.2832G>A p.L944= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as COSV100241277, COSV57061741; called by muse, mutect2
- CATSPER4 | c.312C>T p.I104= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV58792571; called by muse, mutect2, varscan2
- CENPO | c.612C>A p.L204= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV53163910, COSV53173391; called by muse, mutect2, varscan2
- CFHR5 | c.513G>A p.L171= | Silent (SNP) | VAF 39/253 reads (15%) | catalogued as COSV56829740; called by muse, mutect2, varscan2
- CIC | c.522C>G p.L174= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV50677158; called by mutect2, varscan2
- CNKSR1 | c.1350C>T p.L450= (on ENST00000374253 / NM_001297647.2; = p.L443= on NM_006314.3) | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as COSV58794925; called by muse, mutect2, varscan2
- CNKSR1 | c.1491C>G p.L497= (on ENST00000374253 / NM_001297647.2; = p.L490= on NM_006314.3) | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV58792824; called by muse, mutect2, varscan2
- CNTRL | c.1590G>A p.Q530= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as COSV53054275; called by muse, mutect2, varscan2
- CPEB2 | c.2190C>G p.L730= | Silent (SNP) | VAF 52/334 reads (16%) | catalogued as COSV52596012; called by muse, mutect2, varscan2
- CSNK1G1 | c.690G>A p.R230= | Silent (SNP) | VAF 6/75 reads (8%) | catalogued as COSV100274178; called by muse, mutect2
- DNAH3 | c.3501G>A p.K1167= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV54556713; called by muse, mutect2, varscan2
- DNMT1 | c.2505C>T p.I835= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV61584347; called by muse, mutect2, varscan2
- ELP3 | c.306C>T p.I102= | Silent (SNP) | VAF 29/336 reads (9%) | catalogued as COSV99833992; called by muse, mutect2
- EMC2 | c.24C>T p.Y8= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as rs1427069303, COSV99624166; called by muse, mutect2
- ENPP7 | c.1308G>A p.P436= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs372726030, COSV60385791; called by muse, mutect2, varscan2
- ESYT1 | c.255C>T p.L85= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs80169445, COSV57271572, COSV57276066; called by muse, mutect2, varscan2
- FBXO21 | c.1224G>A p.L408= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs764977519, COSV57975242; called by muse, mutect2, varscan2
- FMR1NB | c.216C>T p.L72= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as rs141506256, COSV65070997; called by muse, mutect2
- GABRQ | c.1653G>A p.K551= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs75200055, COSV100941275; called by mutect2, varscan2
- GBE1 | c.849C>T p.V283= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as COSV70102375; called by muse, mutect2, varscan2
- GREB1 | c.825C>T p.F275= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV52197578; called by muse, mutect2, varscan2
- GTF2H3 | c.768C>T p.F256= | Silent (SNP) | VAF 48/182 reads (26%) | catalogued as COSV57460167; called by muse, mutect2, varscan2
- HAUS3 | c.405G>A p.L135= | Silent (SNP) | VAF 16/190 reads (8%) | catalogued as COSV99704268; called by muse, mutect2
- HLX | c.639C>G p.L213= | Silent (SNP) | VAF 21/126 reads (17%) | catalogued as COSV65045785; called by muse, mutect2, varscan2
- HMGN1 | c.102G>C p.A34= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV55742325, COSV99903284; called by muse, mutect2
- IFNAR1 | c.711C>T p.V237= | Silent (SNP) | VAF 59/221 reads (27%) | catalogued as COSV54251931; called by muse, mutect2, varscan2
- KCNH5 | c.289C>T p.L97= | Silent (SNP) | VAF 42/181 reads (23%) | catalogued as COSV59780188; called by muse, mutect2, varscan2
- KIF14 | c.2031G>C p.T677= | Silent (SNP) | VAF 15/477 reads (3%) | catalogued as COSV100950861; called by muse, mutect2
- KIT | c.1248G>A p.L416= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV55396253, COSV99854331; called by muse, mutect2
- KRT71 | c.600G>A p.V200= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as COSV57293375; called by muse, mutect2, varscan2
- LMOD1 | c.1770C>G p.L590= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV100939174; called by muse, mutect2
- LRRC39 | c.726C>T p.S242= | Silent (SNP) | VAF 17/445 reads (4%) | catalogued as COSV100734461; called by muse, mutect2
- MCC | c.1230C>A p.L410= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as COSV100202634; called by muse, mutect2
- MGA | c.7869C>G p.L2623= (on ENST00000219905 / NM_001164273.1; = p.L2414= on NM_001080541.2) | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as rs547913855, COSV54964320; called by muse, mutect2, varscan2
- MUC2 | c.4059G>A p.Q1353= | Silent (SNP) | VAF 31/126 reads (25%) | called by muse, mutect2, varscan2
- MYH4 | c.900C>G p.L300= | Silent (SNP) | VAF 44/174 reads (25%) | catalogued as COSV55127488; called by muse, mutect2, varscan2
- MYMK | c.405G>A p.Q135= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV101301152; called by muse, mutect2
- NBR1 | c.2900G>A p.*967= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs569034474, COSV57836080; called by muse, mutect2, varscan2
- NSMCE3 | c.666C>T p.L222= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV54290577; called by muse, mutect2, varscan2
- NTNG1 | c.282G>A p.A94= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as rs1230131006, COSV53962010, COSV99637567; called by muse, mutect2
- OR10G8 | c.735C>T p.I245= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as rs748588345, COSV70908219; called by muse, mutect2, varscan2
- OR7C1 | c.876G>C p.L292= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV50184637; called by muse, mutect2, varscan2
- P2RX3 | c.1098G>A p.L366= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as rs1265028255, COSV99628666; called by muse, mutect2
- PCDHAC1 | c.2475G>C p.L825= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV53850613, COSV53872804; called by muse, mutect2, varscan2
- PCDHB8 | c.2388C>T p.F796= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as COSV50825301, COSV99176442; called by muse, mutect2, varscan2
- PLG | c.240G>A p.R80= | Silent (SNP) | VAF 52/265 reads (20%) | catalogued as COSV51986872; called by muse, mutect2, varscan2
- PLXNA2 | c.4821C>T p.I1607= | Silent (SNP) | VAF 8/165 reads (5%) | catalogued as COSV100885516; called by muse, mutect2
- PNCK | c.258C>T p.L86= (on ENST00000340888 / NM_001366975.1; = p.L169= on NM_001039582.3) | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV61743956; called by muse, mutect2, varscan2
- POFUT2 | c.753C>T p.D251= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs201577734; called by mutect2, varscan2
- RAC2 | c.237C>T p.L79= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1309978838, COSV50775140, COSV50775690; called by muse, varscan2
- RNF20 | c.1437C>T p.L479= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV101206529; called by muse, mutect2
- RYR3 | c.3534C>T p.F1178= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs1015327748, COSV66785224; called by muse, mutect2, varscan2
- S100A13 | c.150C>G p.L50= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs781660855, COSV52681330; called by muse, mutect2, varscan2
- SP2 | c.195G>A p.R65= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV100947195; called by muse, mutect2
- SPTA1 | c.225C>T p.I75= | Silent (SNP) | VAF 38/182 reads (21%) | catalogued as COSV63760665; called by muse, mutect2, varscan2
- TMTC2 | c.906C>T p.L302= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as COSV58285598; called by muse, mutect2, varscan2
- TTC3 | c.1788C>T p.L596= | Silent (SNP) | VAF 41/169 reads (24%) | catalogued as COSV61293604; called by muse, mutect2, varscan2
- TTN | c.86187C>T p.L28729= (on ENST00000591111; = p.L21305= on NM_003319.4) | Silent (SNP) | VAF 19/245 reads (8%) | catalogued as COSV100614132; called by muse, mutect2
- TYW5 | c.906C>G p.V302= | Silent (SNP) | VAF 41/143 reads (29%) | catalogued as COSV60667561; called by muse, mutect2, varscan2
- UNC79 | c.1812C>G p.L604= (on ENST00000393151 / NM_001346218.2; = p.L427= on NM_020818.5) | Silent (SNP) | VAF 7/108 reads (6%) | catalogued as COSV56406518; called by muse, mutect2
- USP44 | c.1662C>G p.L554= | Silent (SNP) | VAF 15/251 reads (6%) | catalogued as COSV99311869; called by muse, mutect2
- WASHC5 | c.1503G>A p.L501= | Silent (SNP) | VAF 29/180 reads (16%) | catalogued as COSV59201072; called by muse, mutect2, varscan2
- WDFY3 | c.561G>A p.Q187= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV55715476, COSV55716193; called by muse, mutect2, varscan2
- XYLT2 | c.2448G>A p.L816= | Silent (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2
- ZC2HC1C | c.702G>C p.L234= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV53173321; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2235G>A p.K745= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV60159101; called by muse, mutect2, varscan2
- ZNF22 | c.378C>T p.L126= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV53584334, COSV53585297; called by muse, mutect2, varscan2
- ZNF254 | c.327G>A p.L109= | Silent (SNP) | VAF 33/198 reads (17%) | catalogued as COSV61642306; called by muse, mutect2, varscan2
- ZNF550 | c.471T>C p.L157= | Silent (SNP) | VAF 9/178 reads (5%) | catalogued as COSV100286639; called by muse, mutect2
- ZNF652 | c.1350C>T p.F450= | Silent (SNP) | VAF 6/99 reads (6%) | catalogued as rs1223090267, COSV100755599; called by muse, mutect2
- C5orf64 | n.512+52050C>T | Intron (SNP) | VAF 4/73 reads (5%) | called by muse, mutect2
- KLRD1 | c.-1C>T | 5'UTR (SNP) | VAF 46/270 reads (17%) | catalogued as rs373793319; called by muse, mutect2, varscan2
- MIR193B | n.23G>C | RNA (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2, varscan2
- MIR518D | n.84G>A | RNA (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- MIR522 | n.84G>C | RNA (SNP) | VAF 26/170 reads (15%) | catalogued as rs749713294; called by muse, mutect2, varscan2
- NIN | c.-21-1107G>A | Intron (SNP) | VAF 16/68 reads (24%) | catalogued as rs1480790621, COSV99813618; called by muse, mutect2
- PREP | c.-141C>T | 5'UTR (SNP) | VAF 28/1218 reads (2%) | catalogued as COSV100963952; called by muse, mutect2
- TMEM196 | c.*32G>C | 3'UTR (SNP) | VAF 65/302 reads (22%) | catalogued as rs1437363518, COSV68254067, COSV68256756; called by muse, mutect2, varscan2
